Somatic mutation profile of tumor specimen 0DDKEQ from CCDI case PBBNJH, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 9.0 years (3,278 days).
Specimen 0DDKEQ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb5e5070-6097-4731-9a4e-d40d5f7acf79.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDKER (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a74a04d9-8312-4545-a623-ea6ddb221b43

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRT27 | c.10C>T p.R4C | Missense Mutation (SNP) | VAF 216/1002 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs149927735; called by muse, mutect2, varscan2
- MMP2 | c.794T>C p.F265S | Missense Mutation (SNP) | VAF 34/820 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1567374655; called by muse, mutect2
- TRIP11 | c.1672G>C p.D558H | Missense Mutation (SNP) | VAF 39/1482 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.426); catalogued as rs1289529839; called by muse, mutect2
- BCOR | c.4024C>T p.Q1342* (on ENST00000378444 / NM_001123385.2; = p.Q1308* on NM_017745.6) | Nonsense Mutation (SNP) | VAF 241/403 reads (60%) | called by muse, mutect2, varscan2
- EBF2 | c.1529T>G p.I510S | Missense Mutation (SNP) | VAF 20/476 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); called by muse, mutect2
- ICE2 | c.408+2T>C p.X136_splice | Splice Site (SNP) | VAF 20/540 reads (4%) | called by muse, mutect2
